Gene-level copy-number profile of specimen HCM-BROD-0339-C43-85M from HCMI case HCM-BROD-0339-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 36.3 years (13,251 days).
Specimen HCM-BROD-0339-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1c2b8094-ecae-4fe7-b687-6430692ff6e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0339-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,745 have no estimate.
https://portal.gdc.cancer.gov/files/11964430-91c0-446b-970f-18ef6b53ded3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 452; copy number 1: 175; copy number 2: 40,584; copy number 3: 5,178; copy number 4: 11,610; copy number 5: 849; copy number 6: 7; copy number 7: 3; copy number 8: 14; copy number 9: 1; copy number 18: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 879 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,789,130–31,855,568, 3 genes, copy number 5 (within-gene range 2–5): AL354919.2, SPOCD1, AL354919.1.
- chr6:391,752–26,108,135, 426 genes, copy number 5 (broad region; genes not listed).
- chr6:26,269,405–29,831,125, 201 genes, copy number 5–6 (broad region; genes not listed).
- chr6:30,466,452–31,308,549, 66 genes, copy number 5 (broad region; genes not listed).
- chr6:60,789,805–66,728,904, 40 genes, copy number 5–8: AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr7:104,738,597–104,804,107, 1 gene, copy number 6 (within-gene range 4–6): LHFPL3-AS1.
- chr8:42,151,772–42,207,709, 3 genes, copy number 6: AC103724.3, AP3M2, PLAT.
- chr9:60,914,407–60,964,196, 5 genes, copy number 18: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr12:21,797,401–22,618,868, 15 genes, copy number 5 (within-gene range 4–5): ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1.
- chr12:22,699,859–23,188,807, 1 gene, copy number 5 (within-gene range 4–5): AC084816.1.
- chr12:24,212,421–24,775,565, 7 genes, copy number 5: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P.
- chr12:24,949,163–25,108,334, 4 genes, copy number 5 (within-gene range 4–5): AC026310.1, BRI3P2, C12orf77, IRAG2.
- chr12:25,195,216–25,386,241, 5 genes, copy number 5: ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1.
- chr12:25,936,683–27,502,185, 32 genes, copy number 5 (within-gene range 4–5): RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1.
- chr12:27,710,822–27,824,382, 8 genes, copy number 5: MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3.
- chr12:28,133,249–28,581,511, 6 genes, copy number 5 (within-gene range 4–5): CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P.
- chr12:28,821,975–28,978,685, 2 genes, copy number 5: AC022081.1, AC024255.1.
- chr12:32,000,375–32,072,880, 3 genes, copy number 5: AC016957.2, AC016957.1, AC048344.2.
- chr12:33,374,238–33,455,452, 4 genes, copy number 5: SYT10, AC023158.1, AC023158.2, AC016956.1.
- chr13:57,204,379–57,204,799, 1 gene, copy number 9: MTCO2P3.
- chr15:74,719,542–74,803,198, 4 genes, copy number 5–7: CYP1A1, CYP1A2, CSK, MIR4513.
- chr17:83,104,255–83,221,442, 3 genes, copy number 5 (within-gene range 4–5): AC144831.1, AC139099.3, AC139099.2.
- chr20:3,927,309–4,195,953, 6 genes, copy number 5 (within-gene range 4–5): RNF24, FTLP3, RPL21P2, AL356414.1, SMOX, LINC01433.
- chr20:4,422,186–4,431,732, 1 gene, copy number 5: AL139350.1.
- chr20:16,684,108–16,684,404, 1 gene, copy number 5: AL135938.1.
- chr20:31,465,506–31,487,574, 3 genes, copy number 5: DEFB124, REM1, LINC00028.
- chr20:32,690,180–32,743,467, 2 genes, copy number 5: BAK1P1, COMMD7.
- chr20:33,161,768–33,854,366, 26 genes, copy number 5: BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B.

Autosomal genes at a single copy (total copy number 1): 175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
